Somatic mutation profile of tumor specimen TCGA-VQ-AA69-01A (aliquot TCGA-VQ-AA69-01A-11D-A410-08) from TCGA case TCGA-VQ-AA69, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 35.8 years (13,087 days).
Specimen TCGA-VQ-AA69-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25bf9bff-8f2b-4e76-88bc-d384519b5247.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA69-10A (Blood Derived Normal), aliquot TCGA-VQ-AA69-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b402db67-156d-4db5-97f1-ef5035cd9a2c

The open-access MAF lists 74 somatic variants for this specimen: 50 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 21, Nonsense Mutation 4, RNA 2, 3'Flank 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 17/30 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 33/40 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADA2 | c.950C>T p.T317M (on ENST00000262607; = p.T76M on NM_177405.3) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs146788085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM23 | c.1528G>A p.V510M | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs540276873, COSV100008173; called by muse, mutect2, varscan2
- ADGRE1 | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs1281292203, COSV99165491; called by muse, mutect2, varscan2
- ATP6V0A4 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100023302; called by muse, mutect2, varscan2
- BNC2 | c.60G>T p.R20S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1344217950, COSV101033769; called by muse, mutect2, varscan2
- C10orf62 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs768730543, COSV101035282; called by muse, mutect2, varscan2
- CD109 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779599680, COSV99754027; called by muse, mutect2, varscan2
- DCDC1 | c.4895C>A p.A1632E (on ENST00000597505 / NM_001367979.1; = p.A739E on NM_020869.3) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs759005244, COSV100360670; called by muse, mutect2, varscan2
- EPAS1 | c.1735C>A p.P579T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99763357; called by muse, mutect2
- ERN2 | c.1737C>G p.C579W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99891858; called by muse, mutect2, varscan2
- FAT2 | c.8641G>A p.G2881R | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776351095, COSV99943524; called by muse, mutect2, varscan2
- FCER2 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT tolerated (0.39); PolyPhen benign (0.227); catalogued as COSV60917665; called by muse, mutect2, varscan2
- FCGR1A | c.632G>A p.S211N | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV100977301; called by muse, mutect2, varscan2
- GRIA1 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587776937, CM1211454, COSV53598273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HERC5 | c.2657G>T p.R886I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99987916; called by muse, mutect2, varscan2
- HPCAL1 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV100324104; called by muse, mutect2, varscan2
- IGHD | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs754735742, COSV101162961, COSV101163044; called by muse, mutect2, varscan2
- IGHM | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.37); catalogued as rs782313197; called by muse, mutect2, varscan2
- LRRIQ1 | c.1820T>A p.I607N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs1378341869, COSV101280632; called by muse, mutect2, varscan2
- MAGEC1 | c.653del p.P218Lfs*20 | Frame Shift Del (DEL) | VAF 57/132 reads (43%) | catalogued as COSV53568684; called by mutect2, pindel, varscan2
- MAP2K3 | c.674C>T p.A225V (on ENST00000342679 / NM_145109.3; = p.A196V on NM_002756.4) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100383306; called by muse, mutect2
- MLYCD | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs775855312, COSV99299361; called by muse, varscan2
- NLRP4 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs772339690, COSV100016655; called by muse, mutect2, varscan2
- NR1D1 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs147554352; called by muse, mutect2, varscan2
- PABPC3 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs752446615, COSV55802801; called by muse, mutect2, varscan2
- PCDHB2 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV50595276; called by muse, mutect2, varscan2
- PCDHGA9 | c.2422C>A p.P808T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.065); catalogued as rs1203371481, COSV99542050; called by mutect2, varscan2
- PTCHD4 | c.2011G>C p.V671L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV100261228; called by muse, mutect2, varscan2
- RBBP5 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99196855; called by muse, mutect2, varscan2
- RBM46 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1222362262, COSV99908248; called by muse, mutect2, varscan2
- SERPINB4 | c.64T>A p.S22T | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.272); catalogued as COSV100345839; called by muse, mutect2, varscan2
- SLFN5 | c.1829G>A p.C610Y | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1300774477, COSV100249745; called by muse, mutect2, varscan2
- SPTLC1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs143754785; called by muse, mutect2, varscan2
- SV2A | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs782707236, COSV64964440; called by muse, mutect2, varscan2
- SVEP1 | c.3429T>G p.C1143W | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100238485; called by muse, mutect2, varscan2
- TAS1R2 | c.1230C>A p.C410* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100946115, COSV100946279; called by muse, mutect2, varscan2
- THSD7B | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99754218; called by muse, mutect2
- TMEM132E | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV100396550; called by muse, mutect2, varscan2
- TOR1AIP1 | c.791C>G p.S264* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99621505, COSV99621586; called by muse, mutect2, varscan2
- UBE3B | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs749157533, COSV61072875; called by muse, mutect2, varscan2
- USH1G | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs1455989900, COSV100140547; called by muse, mutect2, varscan2
- VPS8 | c.1621C>T p.R541* (on ENST00000625842 / NM_001349294.1; = p.R539* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as rs766165591, COSV99067714; called by muse, mutect2, varscan2
- XIRP2 | c.1582C>A p.Q528K (on ENST00000628543; = p.Q703K on NM_152381.6) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.468); catalogued as COSV54703674; called by muse, mutect2, varscan2
- ZAN | c.4069C>T p.R1357W | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs745652714, COSV61816676; called by muse, mutect2, varscan2
- ZNF599 | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1273586911, COSV100251218, COSV61395938; called by muse, mutect2, varscan2
- ZNF804A | c.3287C>T p.T1096I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV100168887; called by muse, mutect2, varscan2
- P2RX4 | c.826_828del p.F276del | In Frame Del (DEL) | VAF 23/47 reads (49%) | called by mutect2, pindel, varscan2
- ADCY5 | c.828C>T p.A276= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs374267158, COSV71901374; called by muse, mutect2, varscan2
- CDC20B | c.1131A>G p.G377= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99697161; called by muse, mutect2, varscan2
- EMX1 | c.828G>A p.T276= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1235249095, COSV50689617; called by muse, mutect2, varscan2
- GDF15 | c.486G>A p.P162= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs777034751, COSV99416222; called by muse, varscan2
- HK3 | c.1674C>T p.G558= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs141954469; called by muse, mutect2, varscan2
- KCNH8 | c.1284G>A p.T428= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs769829596, COSV100110427; called by muse, mutect2, varscan2
- KDM5B | c.4548C>T p.V1516= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV99350970; called by muse, mutect2, varscan2
- NKX2-1 | c.600G>A p.L200= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100701964; called by muse, mutect2, varscan2
- NUTM2F | c.1213C>T p.L405= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV99480249; called by muse, mutect2, varscan2
- PCDH8 | c.3090C>T p.V1030= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV100131874; called by muse, mutect2, varscan2
- PHB | c.474C>T p.A158= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as rs201875820, COSV100303219; called by muse, mutect2, varscan2
- PLCE1 | c.3153C>A p.G1051= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99595855; called by muse, mutect2, varscan2
- POGLUT2 | c.177G>C p.G59= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs760388907, COSV99958919; called by muse, mutect2, varscan2
- POTEE | c.1617C>T p.I539= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as rs753290855, COSV100388403; called by muse, mutect2, varscan2
- SCARF2 | c.2163C>T p.T721= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs1166078282, COSV99839366; called by muse, varscan2
- SLC6A1 | c.54C>T p.S18= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV55113270; called by muse, mutect2, varscan2
- SNCAIP | c.1200C>T p.C400= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs772706842, COSV54417636; called by muse, mutect2
- SON | c.5910C>G p.R1970= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1458954705, COSV51667766; called by muse, varscan2
- TRAPPC9 | c.2853G>A p.P951= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs754079193, COSV66911170; ClinVar: likely benign; called by muse, mutect2, varscan2
- UAP1L1 | c.1011C>T p.T337= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100814497; called by muse, mutect2, varscan2
- ZNF500 | c.630G>A p.A210= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs374254046; called by muse, varscan2
- HOXC10 | chr12:53991789 G>A | 3'Flank (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100329113; called by muse, mutect2, varscan2
- LINC01587 | n.268A>G | RNA (SNP) | VAF 22/45 reads (49%) | catalogued as rs1331237771; called by muse, mutect2, varscan2
- LPAL2 | n.110G>A | RNA (SNP) | VAF 95/267 reads (36%) | catalogued as rs757412365; called by muse, mutect2, varscan2
